Somatic mutation profile of tumor specimen TCGA-A5-A0GI-01A (aliquot TCGA-A5-A0GI-01A-11W-A062-09) from TCGA case TCGA-A5-A0GI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 63.5 years (23,195 days).
Specimen TCGA-A5-A0GI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50608ec2-e80d-4c2d-9a3b-e41d2d8272ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GI-10A (Blood Derived Normal), aliquot TCGA-A5-A0GI-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/992c1d55-cfe8-4405-8c9d-11f41bc1959a

The open-access MAF lists 386 somatic variants for this specimen: 305 protein-altering or splice-affecting, 81 silent.
By variant classification: Missense Mutation 211, Silent 81, Frame Shift Del 57, Nonsense Mutation 16, Frame Shift Ins 13, Splice Site 5, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 99/236 reads (42%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 58/157 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 18/292 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 212/513 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- PIK3CA | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 54/119 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRKRA | c.267_268del p.H89Qfs*22 | Frame Shift Del (DEL) | VAF 16/157 reads (10%) | catalogued as rs730880307; ClinVar: pathogenic; called by mutect2, pindel
- AACS | c.359-2A>G p.X120_splice | Splice Site (SNP) | VAF 271/709 reads (38%) | catalogued as COSV55538770; called by muse, mutect2, varscan2
- AARS1 | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs763779591, COSV55748728; called by muse, mutect2
- ABCA1 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 203/436 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs562901144, COSV66064583; called by muse, mutect2, varscan2
- ABCA9 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 48/720 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs370277695; called by muse, mutect2
- AC004593.2 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV56096298; called by muse, mutect2, varscan2
- ACAD10 | c.908G>T p.R303M | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100564130; called by muse, mutect2
- ACADSB | c.390A>T p.K130N | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62551127; called by muse, mutect2, varscan2
- ACSL5 | c.517C>G p.H173D (on ENST00000354273; = p.H229D on NM_016234.3) | Missense Mutation (SNP) | VAF 193/465 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV61132214; called by muse, mutect2, varscan2
- ACSS3 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 388/920 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs1055194880, COSV54092182, COSV99698485; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 66/271 reads (24%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY1 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 107/232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs544038944, COSV52038633; called by muse, mutect2, varscan2
- ADGRG4 | c.7636A>G p.T2546A | Missense Mutation (SNP) | VAF 406/936 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54961940; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 35/99 reads (35%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- AHSA1 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 64/166 reads (39%) | catalogued as COSV53632642; called by muse, mutect2, varscan2
- ANGEL1 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as rs773527799, COSV51874413; called by muse, mutect2, varscan2
- ANKDD1A | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs553148491, COSV60353072; called by muse, mutect2, varscan2
- ANKRD13A | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 169/375 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55677348; called by muse, mutect2, varscan2
- ANXA2 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV100221992; called by muse, mutect2
- AP3M2 | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99441539; called by muse, mutect2
- APOL4 | c.962C>A p.S321Y (on ENST00000352371 / NM_145660.2; = p.S318Y on NM_030643.4) | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1255443204, COSV60654247, COSV60654958; called by muse, mutect2
- APOL4 | c.317A>G p.E106G (on ENST00000352371 / NM_145660.2; = p.E103G on NM_030643.4) | Missense Mutation (SNP) | VAF 137/339 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV60654968; called by muse, mutect2, varscan2
- ARFGAP2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs888741559, COSV60301613; called by muse, mutect2, varscan2
- ARHGAP22 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50959159; called by muse, mutect2, varscan2
- ARSL | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 130/310 reads (42%) | catalogued as COSV66965543; called by muse, mutect2, varscan2
- BLMH | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 197/429 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV55586231; called by muse, mutect2, varscan2
- BMT2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 60/554 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376187358; called by muse, mutect2, varscan2
- BTNL2 | c.1171del p.H391Tfs*19 | Frame Shift Del (DEL) | VAF 52/411 reads (13%) | catalogued as rs1279606542; called by mutect2, pindel, varscan2
- C12orf50 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 14/241 reads (6%) | catalogued as rs146623464, COSV53894182; called by muse, mutect2
- C1QC | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV65889889; called by muse, varscan2
- C2orf78 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 14/353 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV101280960; called by muse, mutect2
- CACNA1E | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 152/459 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62406570; called by muse, mutect2, varscan2
- CACNG7 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55815917; called by muse, mutect2, varscan2
- CARD6 | c.2297T>C p.F766S | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99620763; called by muse, mutect2
- CATSPER1 | c.1017del p.G340Afs*14 | Frame Shift Del (DEL) | VAF 168/459 reads (37%) | catalogued as COSV100376228; called by mutect2, pindel, varscan2
- CBL | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV50647867; called by muse, mutect2, varscan2
- CC2D1A | c.1672T>A p.F558I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV58784848; called by muse, mutect2, varscan2
- CCDC102B | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV60148321; called by muse, mutect2, varscan2
- CCDC160 | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV66251795; called by muse, mutect2, varscan2
- CCDC18 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | catalogued as rs200045120; called by muse, mutect2, varscan2
- CCDC62 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV53435676; called by muse, mutect2, varscan2
- CD22 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323180; called by muse, mutect2
- CD99L2 | c.646A>G p.S216G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV60937440; called by muse, mutect2, varscan2
- CDH18 | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV56941921; called by muse, mutect2, varscan2
- CDH19 | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 159/334 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.073); catalogued as COSV50966427; called by muse, mutect2, varscan2
- CDH4 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs770841734, COSV100848769; called by muse, mutect2
- CDHR5 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.382); catalogued as rs1350269268, COSV51564731; called by muse, varscan2
- CEP164 | c.4249C>T p.R1417W | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs745904143, COSV54043770; called by muse, mutect2, varscan2
- COL9A2 | c.25dup p.R9Pfs*18 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as rs754420454; called by mutect2, varscan2
- CTNNAL1 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 304/706 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs780557048, COSV100336512; called by muse, mutect2
- CTTN | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV57234235; called by muse, mutect2, varscan2
- CUL9 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52731450; called by muse, mutect2, varscan2
- CUX1 | c.3082T>A p.S1028T | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV52907241; called by muse, mutect2, varscan2
- CYP46A1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55895696; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | catalogued as COSV99245498; called by mutect2, varscan2
- DCAF12L2 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV63583078, COSV63584603; called by muse, mutect2, varscan2
- DDX60L | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 43/734 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99487570; called by muse, mutect2
- DMC1 | c.766dup p.I256Nfs*6 | Frame Shift Ins (INS) | VAF 37/105 reads (35%) | catalogued as rs762406860; called by mutect2, pindel, varscan2
- DNAAF2 | c.1985A>G p.N662S | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV53572296; called by muse, mutect2
- DNAH17 | c.3399G>T p.K1133N | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV67758451; called by muse, mutect2, varscan2
- DNAH9 | c.5336T>C p.I1779T | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52362404; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 44/112 reads (39%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNMT3A | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV53043412; called by muse, mutect2, varscan2
- DOP1B | c.4876C>T p.R1626* | Nonsense Mutation (SNP) | VAF 53/102 reads (52%) | catalogued as rs373514422, COSV67694472; called by muse, mutect2, varscan2
- DPP8 | c.1964A>T p.D655V (on ENST00000341861 / NM_001320875.2; = p.D639V on NM_017743.6) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV55681075; called by muse, mutect2, varscan2
- ECHDC2 | c.814C>T p.R272W (on ENST00000371522 / NM_001198961.2; = p.R241W on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs547269897, COSV100597436, COSV100597612; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as rs374894345; called by muse, mutect2, varscan2
- EEF1D | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs754445545, COSV57821428; called by muse, mutect2, varscan2
- ENPP3 | c.2378C>T p.T793I | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs1362299810, COSV62955368; called by muse, mutect2, varscan2
- EPHA2 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV64454009; called by muse, mutect2, varscan2
- EPHB3 | c.319G>C p.V107L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs761829006, COSV57807553; called by muse, mutect2, varscan2
- ETNPPL | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 121/288 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56595423; called by muse, mutect2, varscan2
- EXOC1 | c.2259dup p.E754Rfs*23 | Frame Shift Ins (INS) | VAF 42/108 reads (39%) | catalogued as rs961507271; called by mutect2, varscan2
- FAM20A | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 210/513 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56837559; called by muse, mutect2, varscan2
- FBN2 | c.3509G>T p.R1170M | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52529320; called by muse, mutect2, varscan2
- FBP1 | c.710A>T p.N237I | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV64689681; called by muse, mutect2, varscan2
- FIG4 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV57789264; called by muse, mutect2, varscan2
- FNBP1L | c.1169C>T p.P390L (on ENST00000271234 / NM_001164473.2; = p.P332L on NM_017737.5) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV53095199; called by muse, mutect2, varscan2
- FOXN4 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs144504080; called by muse, mutect2
- GABBR2 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758668397, COSV52312016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABBR2 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99409992; called by muse, mutect2
- GANAB | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100648021; called by muse, mutect2
- GATAD2A | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as rs768702148, COSV53073044; called by muse, mutect2, varscan2
- GCN1 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.618); catalogued as COSV56111218; called by muse, mutect2, varscan2
- GDF10 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.434); catalogued as rs782019310; called by muse, mutect2, varscan2
- GLS2 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 61/127 reads (48%) | catalogued as COSV61737881; called by muse, mutect2, varscan2
- GP6 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs746018547, COSV59978501; called by mutect2, varscan2
- GPATCH8 | c.1845G>T p.K615N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV100132634; called by muse, mutect2, varscan2
- GPR151 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57039588; called by muse, mutect2, varscan2
- GTF2B | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1366171378, COSV100980532; called by muse, mutect2
- GUCY2F | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV54309757, COSV99484929; called by muse, mutect2
- GYS2 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768287810, COSV99679722; called by muse, mutect2
- H4C11 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1440537115, COSV61827294; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | catalogued as rs748396956; called by mutect2, varscan2
- HCAR2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); catalogued as rs201097098, COSV61024973; called by muse, mutect2, varscan2
- HECW1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764159115, COSV67835274; called by muse, mutect2, varscan2
- HIRIP3 | c.186+1G>A p.X62_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as COSV54231098; called by muse, varscan2
- HOXA6 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs759230509, COSV56074106; called by muse, mutect2, varscan2
- HSD17B4 | c.1321C>T p.P441S (on ENST00000414835 / NM_001199291.3; = p.P416S on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 273/662 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV56337600; called by muse, mutect2, varscan2
- HYDIN | c.15296G>T p.S5099I | Missense Mutation (SNP) | VAF 278/655 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV66640474; called by muse, mutect2, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 42/301 reads (14%) | catalogued as rs746629447; called by mutect2, varscan2
- IL2RG | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV52149459; called by muse, mutect2, varscan2
- ILF3 | c.1622A>G p.Y541C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV51560198; called by muse, mutect2, varscan2
- INPPL1 | c.3006del p.S1003Rfs*128 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs1390835817; called by mutect2, pindel, varscan2
- INTS9 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV68435150; called by muse, mutect2
- IPO4 | c.2647G>A p.A883T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100269002; called by muse, mutect2
- IQCH | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 23/595 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV100245784; called by muse, mutect2
- IRS4 | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV64534967; called by muse, varscan2
- KCNA1 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs780167432, COSV101230206, COSV66838093; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | catalogued as rs1258313537; called by mutect2, varscan2
- KCNA6 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1158730131, COSV54976427; called by muse, mutect2, varscan2
- KCND2 | c.1609dup p.T537Nfs*16 | Frame Shift Ins (INS) | VAF 102/250 reads (41%) | catalogued as rs770990872; called by mutect2, varscan2
- KCNK16 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV64678728; called by muse, varscan2
- KCTD3 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs756673299, COSV52068741; called by muse, mutect2, varscan2
- KDM5A | c.4523G>A p.R1508Q | Missense Mutation (SNP) | VAF 54/499 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs539682097, COSV66994543; called by muse, mutect2, varscan2
- KIF12 | c.469G>A p.V157I (on ENST00000640217; = p.V19I on NM_138424.1) | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.705); catalogued as rs1359742737, COSV65117782; called by muse, mutect2, varscan2
- KNDC1 | c.4579A>G p.N1527D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV58842067; called by muse, mutect2, varscan2
- LAMB4 | c.2303-1G>T p.X768_splice | Splice Site (SNP) | VAF 30/231 reads (13%) | catalogued as COSV52724896; called by muse, mutect2, varscan2
- LIPF | c.1058T>C p.L353P | Missense Mutation (SNP) | VAF 134/456 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.295); catalogued as COSV53285081; called by muse, mutect2, varscan2
- LONRF1 | c.1847+2T>C p.X616_splice | Splice Site (SNP) | VAF 19/179 reads (11%) | catalogued as COSV68037370; called by muse, mutect2, varscan2
- LOXL2 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66692484, COSV66692781; called by muse, mutect2, varscan2
- LPAR5 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as COSV100320999; called by muse, mutect2
- LRP4 | c.3311G>T p.R1104M | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as COSV66137262; called by muse, mutect2, varscan2
- LRRK1 | c.5771G>A p.R1924H | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1472884841, COSV52602772; called by muse, mutect2, varscan2
- M1AP | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51210050; called by muse, mutect2, varscan2
- MAGED1 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 88/644 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as rs1279409349, COSV58514929; called by muse, varscan2
- MAK | c.98A>G p.K33R | Missense Mutation (SNP) | VAF 193/398 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350418617, COSV57566611; called by muse, mutect2, varscan2
- MAP10 | c.105del p.K36Sfs*31 | Frame Shift Del (DEL) | VAF 28/288 reads (10%) | catalogued as COSV69365000; called by pindel, varscan2
- MAST1 | c.3622G>A p.A1208T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99262868; called by muse, mutect2
- MC4R | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs758426526, CM035970, COSV55351515; called by muse, mutect2, varscan2
- MDN1 | c.4883C>T p.S1628F | Missense Mutation (SNP) | VAF 49/469 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV65525529; called by muse, mutect2, varscan2
- MRPL18 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV51706595; called by muse, mutect2, varscan2
- MSH4 | c.2547G>T p.E849D | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV54207271; called by muse, mutect2, varscan2
- MUC5B | c.4517G>A p.R1506Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs368365490; called by muse, mutect2, varscan2
- MYBPC2 | c.2926del p.T976Pfs*76 | Frame Shift Del (DEL) | VAF 46/130 reads (35%) | catalogued as rs757263482; called by mutect2, pindel, varscan2
- MYH10 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV52597202; called by muse, varscan2
- MYOM1 | c.1583T>C p.I528T | Missense Mutation (SNP) | VAF 164/395 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV55296300; called by muse, mutect2, varscan2
- NAE1 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1473031485, COSV99323112; called by muse, mutect2
- NAV1 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs775388093, COSV55217723; called by muse, mutect2, varscan2
- NCKAP1L | c.3154A>G p.I1052V | Missense Mutation (SNP) | VAF 248/530 reads (47%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.935); catalogued as COSV53209693; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NHS | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.725); catalogued as COSV101196589; called by muse, mutect2
- NIPBL | c.1513del p.R505Efs*35 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs34314728; called by pindel, varscan2
- NLRP11 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 44/580 reads (8%) | catalogued as rs751156777, COSV64085872; called by muse, mutect2
- NLRP7 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs771141227, COSV60179065; called by muse, mutect2
- NLRP9 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 136/298 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.348); catalogued as COSV60465802; called by muse, mutect2, varscan2
- NNT | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1395609733, COSV52927353; called by muse, mutect2, varscan2
- NOL4 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 168/387 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV52353883; called by muse, mutect2, varscan2
- NPAS1 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV99451379; called by muse, mutect2
- NPAT | c.2819C>A p.P940H | Missense Mutation (SNP) | VAF 179/423 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53719628; called by muse, mutect2, varscan2
- NRBP1 | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99275002; called by muse, mutect2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 88/218 reads (40%) | catalogued as rs776154715; called by mutect2, varscan2
- OR10H5 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 186/1306 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs746062074, COSV58278016; called by muse, mutect2, varscan2
- OR2A7 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101512211; called by muse, mutect2
- OR3A3 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99351353; called by muse, mutect2
- OR4C3 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 227/467 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs750063838, COSV60588109; called by muse, mutect2, varscan2
- OR51E1 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 573/1287 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV67809520, COSV67810482; called by muse, mutect2, varscan2
- OR52E2 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 41/321 reads (13%) | catalogued as rs746244350, COSV58613048; called by muse, mutect2, varscan2
- OR52K2 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 936/2196 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.208); catalogued as COSV57835514; called by muse, mutect2, varscan2
- OR6Q1 | c.556T>A p.S186T | Missense Mutation (SNP) | VAF 140/1445 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100109899; called by muse, mutect2
- PACS2 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs782149744, COSV57655538; called by muse, mutect2, varscan2
- PC | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs139795235; called by muse, mutect2, varscan2
- PCDHGA6 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.229); catalogued as COSV53934934; called by muse, mutect2, varscan2
- PCDHGB2 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as rs1174960250, COSV53984178; called by muse, mutect2, varscan2
- PCDHGB7 | c.719del p.P240Qfs*23 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs752316020; called by mutect2, pindel, varscan2
- PGR | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 379/880 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54806040; called by muse, mutect2, varscan2
- PIK3CG | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100782849; called by muse, mutect2, varscan2
- PIWIL2 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 141/344 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63252733; called by muse, mutect2, varscan2
- PIWIL3 | c.2375G>T p.R792M | Missense Mutation (SNP) | VAF 160/405 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59996826; called by muse, mutect2, varscan2
- PLEKHA1 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1413191472, COSV100935475; called by muse, mutect2
- PM20D1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 103/174 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs572366251, COSV65649294; called by muse, varscan2
- PNMA3 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as rs201293043, COSV100937597; called by muse, mutect2, varscan2
- PNPLA8 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57553789; called by muse, mutect2, varscan2
- POGK | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV63311985, COSV63312223; called by muse, mutect2, varscan2
- POLL | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54576645; called by muse, mutect2, varscan2
- POLR2B | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108052, COSV58899606; called by muse, mutect2
- PRDM9 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1425057806, COSV57002819, COSV57012319; called by muse, mutect2
- PRKCA | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52590092; called by muse, mutect2, varscan2
- PSTK | c.*1G>T | Splice Region (SNP) | VAF 19/172 reads (11%) | catalogued as COSV100924737; called by muse, mutect2, varscan2
- PTPN13 | c.4550G>A p.R1517Q (on ENST00000411767 / NM_080683.3; = p.R1498Q on NM_006264.3) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs535867974, COSV57412182; called by muse, mutect2, varscan2
- PZP | c.3676C>A p.Q1226K | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.506); catalogued as COSV99737688; called by muse, mutect2
- RAB11FIP5 | c.1796A>G p.H599R | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV50253146; called by muse, mutect2, varscan2
- RARS1 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs755946147, COSV51564857; called by muse, mutect2, varscan2
- RHBDF2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs1201037991, COSV100489376; called by muse, mutect2
- RHOG | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.949); catalogued as COSV99544264; called by muse, mutect2
- RIMBP2 | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55478821; called by muse, mutect2, varscan2
- RIPOR3 | c.1807T>C p.S603P | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99246359; called by muse, mutect2
- RNF103 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 208/502 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1262913118, COSV52896064; called by muse, mutect2, varscan2
- RNF13 | c.322-2A>G p.X108_splice | Splice Site (SNP) | VAF 57/131 reads (44%) | catalogued as rs1164048870, COSV60133048; called by muse, mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 77/200 reads (39%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- RPS6KA3 | c.1881G>T p.E627D | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV65388680; called by muse, mutect2, varscan2
- RTL3 | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 20/168 reads (12%) | catalogued as rs1183033775, COSV58184897, COSV58185563; called by muse, mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SDCCAG8 | c.1027G>T p.V343F | Missense Mutation (SNP) | VAF 210/708 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV59413262; called by muse, mutect2, varscan2
- SERINC3 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 161/414 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV54857729; called by muse, mutect2, varscan2
- SLC11A2 | c.1612G>T p.V538L (on ENST00000394904 / NM_001379455.1; = p.V509L on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/287 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV50372607; called by muse, mutect2, varscan2
- SLC45A4 | c.425C>T p.A142V (on ENST00000517878 / NM_001286646.2; = p.A91V on NM_001080431.2) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs777700279, COSV50149331; called by mutect2, varscan2
- SLC4A3 | c.2637del p.T880Pfs*27 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs1408200784; called by mutect2, pindel, varscan2
- SLCO2A1 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60487511; called by muse, mutect2, varscan2
- SOGA1 | c.2899G>A p.D967N | Missense Mutation (SNP) | VAF 145/322 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV52924676; called by muse, mutect2, varscan2
- SORCS1 | c.3165G>T p.Q1055H | Missense Mutation (SNP) | VAF 125/262 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV53886316; called by muse, mutect2, varscan2
- SPEF2 | c.3392G>T p.R1131L | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs572380741, COSV61551072; called by muse, mutect2, varscan2
- SPG11 | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55998942; called by muse, mutect2, varscan2
- SPTAN1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1218841089, COSV100823514, COSV63988049; called by muse, mutect2
- SSU72 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99357314; called by muse, mutect2
- SSX3 | c.173T>C p.M58T | Missense Mutation (SNP) | VAF 64/2353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100035196; called by muse, mutect2
- SUGP1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55920607; called by muse, mutect2, varscan2
- SYNE1 | c.26140A>G p.S8714G (on ENST00000367255 / NM_182961.4; = p.S8666G on NM_033071.3) | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99562982; called by muse, mutect2
- TALDO1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs773023043, COSV59797551; called by muse, mutect2, varscan2
- TANC1 | c.2902G>A p.G968S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310313241, COSV55086025; called by muse, mutect2
- TARS2 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64696303; called by muse, mutect2, varscan2
- TBC1D7 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.283); catalogued as COSV100568600; called by muse, mutect2, varscan2
- TBC1D8B | c.1437G>T p.K479N | Missense Mutation (SNP) | VAF 204/482 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52181220; called by muse, mutect2, varscan2
- TCEA1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 54/789 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67172521; called by muse, mutect2
- TEK | c.2456T>C p.L819P | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66227435, COSV66227855; called by muse, mutect2
- TENM1 | c.1790T>C p.I597T | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV64437658; called by muse, mutect2, varscan2
- TEX55 | c.1585del p.L529* | Frame Shift Del (DEL) | VAF 234/593 reads (39%) | catalogued as rs865906615; called by mutect2, pindel, varscan2
- TG | c.4504G>A p.A1502T | Missense Mutation (SNP) | VAF 123/322 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV99600684; called by muse, mutect2
- TMPRSS5 | c.937A>G p.R313G | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55424999; called by muse, mutect2, varscan2
- TOR1A | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.082); catalogued as COSV100693927; called by muse, mutect2
- TRAM2 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51733853; called by muse, mutect2, varscan2
- TRERF1 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100550645; called by muse, mutect2
- TRIOBP | c.4102C>T p.R1368W | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.642); catalogued as rs781187217, COSV60381183; called by muse, mutect2, varscan2
- TRPM1 | c.2449G>T p.G817* | Nonsense Mutation (SNP) | VAF 257/606 reads (42%) | catalogued as rs766173103, COSV56638205, COSV56643196; called by muse, mutect2, varscan2
- TTN | c.5967del p.V1990Cfs*56 (on ENST00000591111; = p.V1944Cfs*56 on NM_003319.4) | Frame Shift Del (DEL) | VAF 140/365 reads (38%) | catalogued as COSV59988800; called by mutect2, pindel, varscan2
- TUFT1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100777062; called by muse, mutect2
- UBE2Q1 | c.999G>T p.R333S | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52726251; called by muse, mutect2, varscan2
- UGGT1 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs1481382305, COSV99390682; called by muse, mutect2
- USH2A | c.10730C>T p.T3577I | Missense Mutation (SNP) | VAF 137/444 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV56401319; called by muse, mutect2, varscan2
- VIPR1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs955182482; called by muse, mutect2
- VRTN | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs760738333, COSV56440875, COSV56442452; called by mutect2, varscan2
- WDR36 | c.2578C>T p.R860* | Nonsense Mutation (SNP) | VAF 53/406 reads (13%) | catalogued as COSV72605361; called by muse, mutect2, varscan2
- XKR6 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs201821196; called by muse, mutect2, varscan2
- XRCC6 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV100777822; called by muse, mutect2
- YLPM1 | c.4717C>T p.R1573* | Nonsense Mutation (SNP) | VAF 33/889 reads (4%) | catalogued as COSV99459553; called by muse, mutect2
- YWHAE | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 122/250 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV51983932; called by muse, mutect2, varscan2
- YWHAQ | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.731); catalogued as rs367832498; called by muse, mutect2
- YY1 | c.743C>A p.P248H | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV99216801; called by muse, mutect2, varscan2
- ZBTB16 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV60096500; called by muse, mutect2, varscan2
- ZCCHC17 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 270/635 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60003091; called by muse, mutect2, varscan2
- ZFP82 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 191/444 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368377208; called by muse, mutect2, varscan2
- ZMAT1 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 40/656 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100858779, COSV100858902, COSV65658949; called by muse, mutect2
- ZNF347 | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 195/438 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV61969840; called by muse, mutect2, varscan2
- ZNF347 | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100498272, COSV61969523; called by muse, mutect2
- ZNF468 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 70/645 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs766894350, COSV54695911; called by muse, mutect2, varscan2
- ZNF549 | c.1088G>A p.C363Y (on ENST00000376233 / NM_001199295.2; = p.C350Y on NM_153263.2) | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768320191, COSV53726638; called by muse, mutect2, varscan2
- ZNF555 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV62073571; called by muse, mutect2, varscan2
- ZNF630 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.416); catalogued as COSV52095672, COSV52097504; called by muse, mutect2, varscan2
- ZNF639 | c.156T>A p.Y52* | Nonsense Mutation (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100418419; called by muse, mutect2
- ZNF648 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60571059; called by muse, mutect2, varscan2
- ZNF875 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs761036948, COSV100183297; called by muse, mutect2
- ABL1 | c.3078del p.I1027Sfs*42 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- ALOX12 | c.898del p.L300Sfs*4 | Frame Shift Del (DEL) | VAF 54/400 reads (14%) | called by mutect2, pindel, varscan2
- ATF4 | c.853del p.M285Wfs*36 | Frame Shift Del (DEL) | VAF 33/68 reads (49%) | called by mutect2, pindel, varscan2
- B3GALT5 | c.913del p.E305Kfs*27 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- BRINP2 | c.2345_2346del p.C782* | Frame Shift Del (DEL) | VAF 42/177 reads (24%) | called by mutect2, pindel, varscan2
- CDPF1 | c.96del p.N33Tfs*14 | Frame Shift Del (DEL) | VAF 16/29 reads (55%) | called by mutect2, pindel, varscan2
- CEP290 | c.6397dup p.T2133Nfs*10 | Frame Shift Ins (INS) | VAF 65/636 reads (10%) | called by mutect2, pindel, varscan2
- CHST15 | c.227del p.K76Rfs*11 | Frame Shift Del (DEL) | VAF 90/237 reads (38%) | called by mutect2, pindel, varscan2
- COL25A1 | c.1143del p.G382Dfs*48 | Frame Shift Del (DEL) | VAF 96/255 reads (38%) | called by mutect2, pindel, varscan2
- DDOST | c.1111_1114del p.K371Vfs*26 (on ENST00000415136; = p.K354Vfs*26 on NM_005216.5) | Frame Shift Del (DEL) | VAF 63/156 reads (40%) | called by mutect2, pindel, varscan2
- EPOR | c.80del p.P27Rfs*94 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- EPRS1 | c.2346del p.K782Nfs*6 | Frame Shift Del (DEL) | VAF 140/592 reads (24%) | called by pindel, varscan2
- FAM155B | c.642dup p.D215Rfs*6 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- GALNT5 | c.502del p.A168Lfs*7 | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | called by mutect2, pindel, varscan2
- GPALPP1 | c.848del p.K283Sfs*2 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- HIRA | c.838del p.I280Sfs*37 | Frame Shift Del (DEL) | VAF 57/168 reads (34%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 92/252 reads (37%) | called by mutect2, varscan2
- KIF21A | c.4719del p.D1574Tfs*35 (on ENST00000361418 / NM_001378440.1; = p.D1561Tfs*35 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 217/602 reads (36%) | called by mutect2, pindel, varscan2
- KLHDC2 | c.951del p.K317Nfs*16 | Frame Shift Del (DEL) | VAF 92/240 reads (38%) | called by mutect2, pindel, varscan2
- KRT76 | c.299dup p.S101Qfs*14 | Frame Shift Ins (INS) | VAF 208/474 reads (44%) | called by mutect2, varscan2
- MAP10 | c.247del p.A83Pfs*39 | Frame Shift Del (DEL) | VAF 42/202 reads (21%) | called by pindel, varscan2
- MINPP1 | c.1168del p.L390* | Frame Shift Del (DEL) | VAF 210/529 reads (40%) | called by mutect2, pindel, varscan2
- MYH2 | c.2672del p.N891Mfs*24 | Frame Shift Del (DEL) | VAF 90/695 reads (13%) | called by mutect2, pindel, varscan2
- MYH6 | c.5263_5265del p.E1755del | In Frame Del (DEL) | VAF 56/234 reads (24%) | called by pindel, varscan2
- NHLRC1 | c.847del p.L283Wfs*12 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- NT5DC1 | c.1122dup p.W375Mfs*7 | Frame Shift Ins (INS) | VAF 47/145 reads (32%) | called by mutect2, pindel, varscan2
- OR52E8 | c.787dup p.S263Ffs*10 | Frame Shift Ins (INS) | VAF 44/364 reads (12%) | called by mutect2, varscan2
- PCDHB9 | c.2332_2333insT p.R778Mfs*15 | Frame Shift Ins (INS) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- PTEN | c.190del p.H64Ifs*35 | Frame Shift Del (DEL) | VAF 195/295 reads (66%) | called by mutect2, pindel, varscan2
- PUM2 | c.307_309del p.P103del | In Frame Del (DEL) | VAF 90/245 reads (37%) | called by mutect2, pindel, varscan2
- RECK | c.2054del p.N685Tfs*12 | Frame Shift Del (DEL) | VAF 65/419 reads (16%) | called by mutect2, pindel, varscan2
- SETDB1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 21/516 reads (4%) | called by muse, mutect2
- SI | c.3025_3026del p.K1009Vfs*4 | Frame Shift Del (DEL) | VAF 202/604 reads (33%) | called by mutect2, pindel, varscan2
- SLC44A4 | c.1897del p.H633Tfs*10 | Frame Shift Del (DEL) | VAF 36/84 reads (43%) | called by mutect2, pindel, varscan2
- SLTM | c.1310_1311del p.E437Gfs*12 | Frame Shift Del (DEL) | VAF 108/308 reads (35%) | called by pindel, varscan2
- TAF15 | c.431A>G p.Q144R (on ENST00000605844 / NM_139215.3; = p.Q141R on NM_003487.4) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- TBC1D10C | c.377del p.P126Lfs*164 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- TET3 | c.5243del p.G1748Afs*106 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- TNRC6B | c.4523del p.G1508Vfs*8 (on ENST00000454349 / NM_001162501.2; = p.G1398Vfs*8 on NM_015088.3) | Frame Shift Del (DEL) | VAF 60/178 reads (34%) | called by mutect2, pindel, varscan2
- TRAM1L1 | c.1033del p.R345Efs*14 | Frame Shift Del (DEL) | VAF 154/366 reads (42%) | called by mutect2, varscan2
- TTN | c.66084dup p.G22029Rfs*6 (on ENST00000591111; = p.G14605Rfs*6 on NM_003319.4) | Frame Shift Ins (INS) | VAF 59/134 reads (44%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.2999del p.K1000Rfs*12 | Frame Shift Del (DEL) | VAF 63/176 reads (36%) | called by mutect2, pindel, varscan2
- UNC45A | c.1055dup p.S353Lfs*28 | Frame Shift Ins (INS) | VAF 26/63 reads (41%) | called by mutect2, varscan2
- USP10 | c.1886del p.F629Sfs*41 | Frame Shift Del (DEL) | VAF 21/219 reads (10%) | called by mutect2, pindel, varscan2
- USP31 | c.2195_2196del p.V732Gfs*9 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by pindel, varscan2
- ZCCHC14 | c.2086del p.L696Cfs*107 (on ENST00000268616; = p.L833Cfs*107 on NM_015144.3) | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.8767dup p.S2923Kfs*2 | Frame Shift Ins (INS) | VAF 25/204 reads (12%) | called by mutect2, pindel, varscan2
- ZNF518B | c.3056del p.N1019Tfs*5 | Frame Shift Del (DEL) | VAF 51/423 reads (12%) | called by mutect2, pindel, varscan2
- ABCB11 | c.450C>T p.V150= | Silent (SNP) | VAF 150/327 reads (46%) | catalogued as rs376327318, COSV55595777; called by muse, mutect2, varscan2
- ADAMTS12 | c.4716C>A p.P1572= | Silent (SNP) | VAF 26/644 reads (4%) | catalogued as COSV100710440, COSV61265682; called by muse, mutect2
- ADGRF5 | c.1476C>T p.C492= | Silent (SNP) | VAF 197/525 reads (38%) | catalogued as COSV51937246; called by muse, mutect2, varscan2
- ALDH5A1 | c.516C>T p.R172= | Silent (SNP) | VAF 103/212 reads (49%) | catalogued as COSV62374135; called by muse, mutect2, varscan2
- ALPK1 | c.948T>C p.C316= | Silent (SNP) | VAF 19/196 reads (10%) | catalogued as COSV99454012; called by muse, mutect2
- ALPK2 | c.3732C>A p.S1244= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV64494812; called by muse, mutect2, varscan2
- ANKRD22 | c.108T>C p.D36= | Silent (SNP) | VAF 30/342 reads (9%) | catalogued as COSV100905470; called by muse, mutect2
- AP3B2 | c.2364C>A p.S788= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as COSV55611889; called by muse, mutect2, varscan2
- ATG2A | c.2589C>T p.P863= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs769048803, COSV65967726; called by muse, mutect2, varscan2
- CACNB1 | c.1506C>T p.A502= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1314130304, COSV59999546; called by muse, mutect2, varscan2
- CAMTA1 | c.2679C>T p.G893= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV57914381; called by muse, varscan2
- CDCA8 | c.630G>T p.R210= | Silent (SNP) | VAF 84/184 reads (46%) | catalogued as rs376634167, COSV59239854; called by muse, mutect2, varscan2
- CFAP20DC | c.804G>A p.G268= (on ENST00000482387 / NM_001351530.2; = p.G143= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/500 reads (6%) | catalogued as COSV99918648; called by muse, mutect2
- CHD3 | c.3537G>A p.V1179= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- CNR1 | c.879G>A p.A293= | Silent (SNP) | VAF 49/106 reads (46%) | catalogued as rs35057475; called by muse, mutect2, varscan2
- CNTN2 | c.1170G>A p.S390= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as rs1285737396, COSV59351523; called by muse, mutect2, varscan2
- COPA | c.1335C>A p.T445= | Silent (SNP) | VAF 285/980 reads (29%) | catalogued as COSV99615484; called by muse, mutect2, varscan2
- CROT | c.450A>G p.G150= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as COSV58975731; called by muse, mutect2, varscan2
- CSK | c.960G>A p.V320= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs928453152, COSV54974890; called by muse, varscan2
- CTH | c.624T>C p.Y208= | Silent (SNP) | VAF 14/307 reads (5%) | catalogued as COSV100697077; called by muse, mutect2
- DAAM2 | c.1138C>T p.L380= | Silent (SNP) | VAF 18/364 reads (5%) | catalogued as rs1374643000, COSV99225609; called by muse, mutect2
- DAPK1 | c.3990C>T p.L1330= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs958804914, COSV63789596; called by muse, mutect2, varscan2
- DCDC1 | c.33A>G p.E11= | Silent (SNP) | VAF 42/359 reads (12%) | catalogued as COSV60850311; called by muse, mutect2, varscan2
- DENND1C | c.234C>T p.G78= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV67374185; called by muse, mutect2, varscan2
- DHDH | c.87C>T p.H29= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1260928273, COSV55482706; called by muse, mutect2, varscan2
- DNHD1 | c.1458C>T p.I486= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV54440117; called by muse, mutect2, varscan2
- DSCAM | c.3129C>T p.S1043= | Silent (SNP) | VAF 24/371 reads (6%) | catalogued as rs200813926, COSV68025393; called by muse, mutect2
- EXPH5 | c.5349G>A p.L1783= | Silent (SNP) | VAF 57/117 reads (49%) | catalogued as COSV56205225; called by muse, mutect2, varscan2
- GGT5 | c.237C>T p.S79= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs760496253, COSV99571513; called by muse, mutect2
- GPR107 | c.717A>G p.T239= | Silent (SNP) | VAF 49/432 reads (11%) | catalogued as rs372730832; called by muse, mutect2, varscan2
- GPR87 | c.342C>T p.C114= | Silent (SNP) | VAF 80/479 reads (17%) | catalogued as COSV53463844; called by muse, mutect2, varscan2
- GSPT2 | c.81G>A p.P27= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV61214264; called by muse, mutect2
- GUCD1 | c.573T>G p.R191= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV101238117; called by muse, mutect2
- H4C3 | c.132C>T p.V44= | Silent (SNP) | VAF 94/189 reads (50%) | catalogued as COSV58090958; called by muse, mutect2, varscan2
- HBD | c.207A>C p.L69= | Silent (SNP) | VAF 18/500 reads (4%) | catalogued as rs1283286194, COSV99496684; called by muse, mutect2
- HIPK1 | c.867C>G p.L289= | Silent (SNP) | VAF 253/565 reads (45%) | catalogued as rs752003214, COSV65786029, COSV65786822; called by muse, mutect2, varscan2
- HTT | c.5964G>A p.V1988= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as COSV100750721; called by muse, mutect2
- IGFBP3 | c.615G>A p.K205= | Silent (SNP) | VAF 36/241 reads (15%) | catalogued as COSV51872997; called by muse, mutect2, varscan2
- IQCH | c.1984C>A p.R662= | Silent (SNP) | VAF 132/316 reads (42%) | catalogued as COSV60056684; called by muse, mutect2, varscan2
- KLHL4 | c.369C>T p.R123= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV64138958; called by muse, mutect2
- MCFD2 | c.195G>A p.A65= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as rs752268860, COSV60178217; called by muse, mutect2, varscan2
- MKI67 | c.9201C>T p.S3067= | Silent (SNP) | VAF 270/673 reads (40%) | catalogued as COSV64075585; called by muse, mutect2, varscan2
- MKX | c.645C>A p.P215= | Silent (SNP) | VAF 201/441 reads (46%) | catalogued as rs764994992, COSV65392685; called by mutect2, varscan2
- MRGPRX3 | c.123G>A p.A41= | Silent (SNP) | VAF 35/299 reads (12%) | catalogued as rs763180228, COSV66934112; called by muse, mutect2, varscan2
- MYCBP2 | c.4914C>T p.S1638= (on ENST00000357337; = p.S1676= on NM_015057.5) | Silent (SNP) | VAF 24/431 reads (6%) | catalogued as COSV100630270; called by muse, mutect2
- MYH7B | c.3141G>A p.L1047= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs766228940, COSV53422756; called by muse, mutect2, varscan2
- NSD3 | c.261G>A p.Q87= | Silent (SNP) | VAF 413/901 reads (46%) | catalogued as COSV57620676; called by muse, mutect2, varscan2
- NTHL1 | c.162C>T p.P54= (on ENST00000219066; = p.P46= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs752395301, COSV54593581; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTNG1 | c.732C>T p.Y244= | Silent (SNP) | VAF 87/197 reads (44%) | catalogued as rs937656695, COSV53965583; called by muse, mutect2, varscan2
- NUTF2 | c.210G>A p.A70= | Silent (SNP) | VAF 103/226 reads (46%) | catalogued as rs140700348; called by muse, mutect2, varscan2
- OR2L3 | c.424C>T p.L142= | Silent (SNP) | VAF 88/2556 reads (3%) | catalogued as COSV100741876; called by muse, mutect2
- PAPLN | c.3714G>A p.Q1238= (on ENST00000554301; = p.Q1211= on NM_173462.4) | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as COSV53720918; called by muse, mutect2, varscan2
- PCDHA7 | c.2190C>T p.G730= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs1247544483, COSV65335204; called by muse, mutect2, varscan2
- PDE4DIP | c.3777C>A p.S1259= | Silent (SNP) | VAF 29/591 reads (5%) | catalogued as COSV100518991, COSV100520644; called by muse, mutect2
- PDE6B | c.1506C>T p.Y502= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs750323428, COSV55328596; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- PLCB3 | c.366C>T p.A122= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1323094165, COSV54189330; called by muse, mutect2, varscan2
- POU4F2 | c.672C>A p.T224= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV55585674; called by muse, mutect2, varscan2
- PPIP5K2 | c.2973G>A p.L991= | Silent (SNP) | VAF 86/228 reads (38%) | catalogued as COSV58604719; called by muse, mutect2, varscan2
- PPL | c.4326C>T p.T1442= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs781572118, COSV52170342; called by muse, mutect2, varscan2
- PREX1 | c.501C>A p.T167= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as COSV64254289, COSV64255842; called by muse, mutect2, varscan2
- PRG4 | c.1362C>A p.T454= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV63356038; called by muse, mutect2, varscan2
- PTPN12 | c.666T>C p.H222= | Silent (SNP) | VAF 18/428 reads (4%) | catalogued as COSV99950310; called by muse, mutect2
- PWWP3A | c.1926C>G p.A642= (on ENST00000627377; = p.A641= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV60903502; called by muse, mutect2, varscan2
- RELN | c.1875C>A p.S625= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as COSV59019491; called by muse, mutect2, varscan2
- RFWD3 | c.885C>A p.T295= | Silent (SNP) | VAF 18/244 reads (7%) | catalogued as COSV100736231; called by muse, mutect2
- RIOX2 | c.849C>T p.D283= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs201634045, COSV57725087; called by muse, mutect2, varscan2
- SDHA | c.1188G>A p.T396= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as rs778667374, COSV53768159; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- SETDB1 | c.2193C>T p.C731= | Silent (SNP) | VAF 96/310 reads (31%) | catalogued as COSV54988165; called by muse, mutect2, varscan2
- SLC25A35 | c.550C>T p.L184= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1257247378, COSV99873821; called by muse, mutect2
- ST6GALNAC6 | c.69C>T p.R23= | Silent (SNP) | VAF 93/214 reads (43%) | catalogued as COSV52536051; called by muse, mutect2, varscan2
- TET1 | c.5241C>T p.F1747= | Silent (SNP) | VAF 14/312 reads (4%) | catalogued as COSV101018159, COSV65390102; called by muse, mutect2
- THBD | c.1662C>T p.C554= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs903959463, COSV65702039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIAM1 | c.1956C>T p.G652= | Silent (SNP) | VAF 76/157 reads (48%) | catalogued as COSV54562710; called by muse, mutect2, varscan2
- TMCO1 | c.429T>C p.F143= (on ENST00000612311 / NM_001256164.1; = p.F92= on NM_019026.6) | Silent (SNP) | VAF 35/464 reads (8%) | catalogued as COSV100903145; called by muse, mutect2
- TNS1 | c.198C>T p.D66= | Silent (SNP) | VAF 10/288 reads (3%) | catalogued as COSV99410608; called by muse, mutect2
- UTRN | c.7167T>C p.G2389= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as COSV100839874; called by muse, mutect2
- VPS13B | c.8322C>T p.Y2774= | Silent (SNP) | VAF 120/308 reads (39%) | catalogued as COSV62149872; called by muse, mutect2, varscan2
- WNK3 | c.5001T>C p.I1667= | Silent (SNP) | VAF 45/789 reads (6%) | catalogued as COSV100671336; called by muse, mutect2
- ZNF333 | c.1569G>A p.V523= | Silent (SNP) | VAF 61/357 reads (17%) | catalogued as COSV52887350; called by muse, mutect2, varscan2
- ZNF8 | c.384G>A p.P128= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs1306483614, COSV52188678; called by muse, mutect2, varscan2
- ZNF827 | c.3015C>T p.S1005= | Silent (SNP) | VAF 83/182 reads (46%) | catalogued as COSV65229625; called by muse, mutect2, varscan2
